Somatic mutation profile of tumor specimen TCGA-BA-A6DL-01A (aliquot TCGA-BA-A6DL-01A-21D-A30E-08) from TCGA case TCGA-BA-A6DL, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G2; Age at diagnosis: 59.9 years (21,886 days).
Specimen TCGA-BA-A6DL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43209c3d-5379-4a18-83dd-163aa9749ae8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DL-10A (Blood Derived Normal), aliquot TCGA-BA-A6DL-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e700e0ee-6bbe-4cad-94c0-2705b4cfac77

The open-access MAF lists 91 somatic variants for this specimen: 71 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 2, In Frame Ins 1, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 29/178 reads (16%) | catalogued as rs587784098, CM031301, COSV100729678; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 42/154 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRD1 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747226478, COSV99896525; called by muse, mutect2, varscan2
- ARL14 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV100296529; called by muse, mutect2, varscan2
- ASGR2 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99643128; called by muse, mutect2, varscan2
- ATP6V1G3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs944996834, COSV99811001; called by muse, mutect2
- AVPR1A | c.1172A>T p.N391I | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as COSV100146891; called by muse, mutect2, varscan2
- CATSPERB | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1158408399, COSV56431378, COSV99831581; called by muse, mutect2, varscan2
- CATSPERD | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV101062735; called by muse, mutect2, varscan2
- CCR2 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV52749213, COSV99432659; called by muse, mutect2, varscan2
- CHL1 | c.1678G>C p.E560Q (on ENST00000397491 / NM_001253387.1; = p.E576Q on NM_006614.4) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.083); catalogued as COSV99851900; called by muse, mutect2, varscan2
- CLCN2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99658876; called by muse, mutect2, varscan2
- COL6A2 | c.715-1G>T p.X239_splice | Splice Site (SNP) | VAF 14/126 reads (11%) | catalogued as COSV100154047, COSV56014582; called by muse, mutect2, varscan2
- COLEC12 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 62/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404522800, COSV101232126; called by muse, mutect2, varscan2
- CP | c.1713+2T>G p.X571_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99224346; called by muse, mutect2, varscan2
- CRACD | c.2975G>A p.R992Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV99948847, COSV99949774; called by muse, mutect2
- CYP2C8 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752621676, COSV100987990; called by muse, mutect2, varscan2
- DLGAP2 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV101422496; called by muse, mutect2, varscan2
- DNAH8 | c.6178G>T p.V2060F | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100546668; called by muse, mutect2
- DOT1L | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101288757; called by muse, mutect2, varscan2
- EHD2 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99622150; called by muse, mutect2, varscan2
- EPX | c.1976C>A p.T659N | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99836696; called by muse, mutect2, varscan2
- ERO1B | c.806-1G>C p.X269_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99934612; called by muse, mutect2, varscan2
- EVPL | c.2225A>G p.E742G | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101648794; called by muse, mutect2, varscan2
- FAM83D | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54157519, COSV54157747; called by muse, mutect2
- GLI3 | c.3044G>T p.G1015V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101229977; called by muse, mutect2
- GPAT2 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | catalogued as COSV64003457; called by muse, mutect2, varscan2
- GPR50 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.614); catalogued as COSV99506450; called by muse, mutect2, varscan2
- HELQ | c.1017G>T p.W339C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs563330991, COSV99787999; called by muse, mutect2
- HELQ | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99788001; called by muse, mutect2
- HSPA12A | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV65024318; called by muse, mutect2, varscan2
- IKZF3 | c.516A>C p.K172N | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53105248; called by muse, mutect2, varscan2
- IQCF1 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100094936; called by muse, mutect2, varscan2
- KIF21B | c.4759G>A p.D1587N (on ENST00000422435 / NM_001252100.2; = p.D1574N on NM_017596.4) | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs774619563, COSV100144927, COSV59766136; called by muse, mutect2, varscan2
- LRRC4 | c.150C>G p.C50W | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975176, COSV99975178; called by muse, mutect2, varscan2
- MAGT1 | c.188G>A p.R63H (on ENST00000618282 / NM_001367916.1; = p.R95H on NM_032121.5) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.276); catalogued as COSV100800393; called by muse, mutect2, varscan2
- MICALL1 | c.2300A>G p.N767S | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99317486; called by muse, mutect2, varscan2
- MSH4 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV99592214; called by muse, mutect2, varscan2
- MTMR7 | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 26/121 reads (21%) | catalogued as rs759135673, COSV51667541; called by muse, mutect2, varscan2
- MYO18B | c.6271G>T p.D2091Y | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100124568; called by muse, mutect2, varscan2
- NOXRED1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100033179; called by muse, mutect2, varscan2
- PHF19 | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100384366; called by muse, mutect2, varscan2
- PKHD1L1 | c.11245A>G p.T3749A | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101006629; called by muse, mutect2, varscan2
- PLCG2 | c.3417A>T p.E1139D | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100842523; called by muse, mutect2, varscan2
- PPP1R14C | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100745214; called by muse, mutect2
- PRUNE2 | c.183A>G p.I61M | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100943212; called by muse, mutect2, varscan2
- PSMA6 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as COSV99809257; called by muse, mutect2, varscan2
- PSMD13 | c.776C>G p.P259R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100728885; called by muse, mutect2, varscan2
- RFX4 | c.1753G>A p.V585I (on ENST00000392842 / NM_213594.3; = p.V491I on NM_032491.6) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.012); catalogued as rs766270351, COSV57576195; called by muse, mutect2, varscan2
- ROBO1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71392908, COSV71393829; called by muse, mutect2
- SAMD9L | c.1048A>T p.R350W | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100561035; called by muse, mutect2, varscan2
- SLC22A10 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235944; called by muse, mutect2, varscan2
- SLC44A2 | c.815T>A p.L272Q | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV100213385; called by muse, mutect2, varscan2
- SOX13 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99690028; called by muse, mutect2, varscan2
- SRSF8 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs1555107229, COSV101475810; called by muse, mutect2, varscan2
- STKLD1 | c.1577G>C p.G526A | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782376433, COSV100905763; called by muse, mutect2, varscan2
- TARS3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100254896, COSV60108791; called by muse, mutect2, varscan2
- TET2 | c.2722G>T p.G908C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99484143; called by muse, mutect2, varscan2
- TOPORS | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as rs761905502, COSV100859570; called by muse, mutect2
- TRIM10 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562005469, COSV64998313; called by muse, mutect2, varscan2
- WASHC2C | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.519); catalogued as rs782597041, COSV100314141; called by mutect2, varscan2
- WDR17 | c.2929A>G p.M977V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99708056; called by muse, mutect2, varscan2
- XAB2 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV50337096; called by muse, mutect2, varscan2
- ZFPL1 | c.411C>T p.I137= | Splice Region (SNP) | VAF 22/192 reads (11%) | catalogued as rs201531261, COSV51871421; called by muse, mutect2, varscan2
- ZNF287 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101209401; called by muse, mutect2, varscan2
- ZNF416 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV52184981, COSV99543890; called by muse, mutect2
- AKR7L | c.501_503dup p.Y167_Q168insH | In Frame Ins (INS) | VAF 17/87 reads (20%) | called by mutect2, pindel, varscan2
- NSD1 | c.3599_3606del p.R1200Lfs*5 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- OR2T5 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT3 | c.1937del p.P646Lfs*13 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.5679C>T p.Y1893= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101240003; called by muse, mutect2
- BOD1L1 | c.2040A>G p.V680= | Silent (SNP) | VAF 76/291 reads (26%) | catalogued as rs748391083, COSV99240062; called by muse, mutect2, varscan2
- CSMD1 | c.4458G>A p.P1486= (on ENST00000520002; = p.P1485= on NM_033225.6) | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs755542937, COSV100152066, COSV100153089; called by muse, mutect2, varscan2
- DCAF12L2 | c.741G>T p.P247= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV63582152; called by muse, mutect2
- EPHB1 | c.1440C>T p.N480= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV101213871; called by muse, mutect2, varscan2
- FADS2 | c.243C>T p.F81= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs377238578; called by muse, mutect2, varscan2
- GNAS | c.783G>T p.S261= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100007261; called by muse, mutect2
- KLHDC3 | c.949C>T p.L317= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV55064351, COSV99763871; called by muse, mutect2, varscan2
- NBEAL2 | c.4077C>A p.G1359= | Silent (SNP) | VAF 61/180 reads (34%) | catalogued as COSV99437078; called by muse, mutect2, varscan2
- NPAP1 | c.2148C>A p.V716= | Silent (SNP) | VAF 33/226 reads (15%) | catalogued as COSV100275858; called by muse, mutect2, varscan2
- OR8B12 | c.340C>T p.L114= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs558889304, COSV100172887; called by muse, mutect2, varscan2
- PLCB1 | c.2625C>T p.P875= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100571798, COSV100571817; called by muse, mutect2, varscan2
- PRDM13 | c.318G>A p.E106= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100980564; called by muse, mutect2, varscan2
- SP1 | c.462C>T p.N154= (on ENST00000327443 / NM_138473.3; = p.N147= on NM_003109.1) | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV100540793; called by muse, mutect2, varscan2
- SPRING1 | c.90C>T p.F30= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs374834316; called by muse, mutect2, varscan2
- TOGARAM2 | c.1386G>A p.T462= | Silent (SNP) | VAF 77/204 reads (38%) | catalogued as rs527747733, COSV65423208; called by muse, mutect2, varscan2
- TRIM11 | c.1026C>T p.H342= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs746368861, COSV99488789; called by muse, mutect2, varscan2
- TULP4 | c.2673C>T p.F891= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as rs771377537, COSV100893696; called by muse, mutect2, varscan2
- OR3A4P | n.534C>T | RNA (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- PML | c.1710+820A>T | Intron (SNP) | VAF 60/177 reads (34%) | catalogued as COSV99167760; called by muse, mutect2, varscan2
